Somatic mutation profile of tumor specimen C3L-01232-03 (aliquot CPT0239440006) from CPTAC case C3L-01232, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.6 years (18,836 days).
Specimen C3L-01232-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bd77bc0-0f12-47e2-8194-77ae5efc82ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01232-31 (Blood Derived Normal), aliquot CPT0240430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebcf6a4d-6889-4496-9e70-08a12d3b312d

The open-access MAF lists 81 somatic variants for this specimen: 51 protein-altering or splice-affecting, 21 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 21, Intron 5, Nonsense Mutation 3, RNA 2, Splice Site 2, Splice Region 1, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC16A1 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 61/166 reads (37%) | catalogued as rs606231300, CM1411338; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-1G>A p.X225_splice | Splice Site (SNP) | VAF 130/415 reads (31%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>A p.I195N | Missense Mutation (SNP) | VAF 194/533 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 105/298 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV63978276; called by muse, mutect2, varscan2
- ALDH16A1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as rs1015091964; called by muse, mutect2, varscan2
- CASZ1 | c.3437C>T p.T1146M | Missense Mutation (SNP) | VAF 132/346 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756123520; called by muse, mutect2, varscan2
- CHRDL2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs201003334; called by muse, mutect2, varscan2
- DNAH2 | c.9565G>A p.V3189I | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs375285205; called by muse, mutect2, varscan2
- DNAI3 | c.1972C>T p.R658* | Nonsense Mutation (SNP) | VAF 7/86 reads (8%) | catalogued as rs981857804; called by muse, mutect2
- FAM170A | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 108/288 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs369994686; called by muse, mutect2, varscan2
- FMO3 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs146765448, COSV63006943; called by muse, mutect2, varscan2
- GALNT17 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs557986424, COSV61153495, COSV61165790; called by muse, mutect2, varscan2
- GPD1 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs370885973; called by muse, mutect2, varscan2
- GRM8 | c.1423C>A p.Q475K | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV58800811; called by muse, mutect2, varscan2
- HCRTR2 | c.405C>T p.T135= | Splice Region (SNP) | VAF 110/335 reads (33%) | catalogued as rs199900684, COSV63793534; called by muse, mutect2, varscan2
- MROH5 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1470899139, COSV101436139; called by muse, mutect2, varscan2
- NOTCH1 | c.5561G>A p.R1854H | Missense Mutation (SNP) | VAF 248/666 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs878855028, COSV53066047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2G2 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1011627557, COSV60741672, COSV60742813; called by muse, mutect2, varscan2
- OSMR | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as rs551827249; called by muse, mutect2, varscan2
- PABPC5 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV100442529; called by muse, mutect2, varscan2
- PLXNB1 | c.4615C>T p.R1539C | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs775913728; called by muse, mutect2, varscan2
- POT1 | c.1141C>A p.H381N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs1459987627; called by muse, varscan2
- RADX | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV65317939; called by muse, mutect2, varscan2
- RASAL3 | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199734851; called by muse, mutect2, varscan2
- SEL1L2 | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV53157298; called by muse, mutect2, varscan2
- TMEM140 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 127/405 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150916088; called by muse, mutect2, varscan2
- ZNF500 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 56/136 reads (41%) | catalogued as rs755696438; called by muse, mutect2, varscan2
- ZNF99 | c.2082A>C p.K694N | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.529); catalogued as COSV101233945; called by muse, mutect2, varscan2
- BIRC6 | c.9541G>T p.V3181L | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- CBX1 | c.428A>C p.E143A | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CSMD3 | c.745A>T p.S249C | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DEPDC5 | c.3397-2A>G p.X1133_splice (on ENST00000400246; = p.X1202_splice on NM_014662.5) | Splice Site (SNP) | VAF 39/61 reads (64%) | called by muse, mutect2, varscan2
- DNAJC13 | c.3758G>T p.C1253F | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ERICH6B | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 84/122 reads (69%) | SIFT tolerated (0.64); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FRS3 | c.46A>C p.N16H | Missense Mutation (SNP) | VAF 140/354 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HBS1L | c.482A>C p.K161T | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- LRP2 | c.3955T>C p.C1319R | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MPDZ | c.3416A>G p.Q1139R | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MSL3 | c.926C>A p.S309Y (on ENST00000312196 / NM_078629.4; = p.S143Y on NM_006800.4) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NUP210L | c.4035A>T p.K1345N | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- RB1 | c.2529_2530dup p.K844Rfs*6 | Frame Shift Ins (INS) | VAF 31/80 reads (39%) | called by mutect2, pindel, varscan2
- RFX7 | c.2963G>T p.S988I (on ENST00000559447 / NM_001368074.1; = p.S1085I on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/163 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SMN2 | c.865T>C p.C289R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- STARD13 | c.1831A>C p.S611R (on ENST00000336934 / NM_001243476.3; = p.S493R on NM_052851.3) | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- STK31 | c.2957A>C p.D986A | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); called by muse, varscan2
- TMEM241 | c.701G>C p.S234T | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- TRPC6 | c.2453A>G p.D818G | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- USH2A | c.10739A>G p.K3580R | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- WWC3 | c.52A>G p.R18G | Missense Mutation (SNP) | VAF 111/304 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZBTB21 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF692 | c.407C>G p.P136R | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ATP8B1 | c.2223T>C p.N741= | Silent (SNP) | VAF 71/186 reads (38%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.225G>T p.R75= | Silent (SNP) | VAF 106/196 reads (54%) | called by muse, mutect2, varscan2
- COL20A1 | c.3027G>A p.T1009= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as rs368035015; called by muse, mutect2, varscan2
- CYP7A1 | c.636C>T p.F212= | Silent (SNP) | VAF 187/553 reads (34%) | catalogued as rs370087640; called by muse, mutect2, varscan2
- FAT2 | c.10746G>A p.A3582= | Silent (SNP) | VAF 109/287 reads (38%) | catalogued as rs745505451, COSV55828361; called by muse, mutect2, varscan2
- FAT4 | c.1972T>C p.L658= | Silent (SNP) | VAF 65/184 reads (35%) | called by muse, mutect2, varscan2
- FBXL5 | c.1167T>C p.D389= | Silent (SNP) | VAF 28/78 reads (36%) | called by muse, varscan2
- FBXO24 | c.945C>T p.Y315= (on ENST00000241071 / NM_033506.3; = p.Y353= on NM_012172.5) | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as rs369063915; called by muse, mutect2
- GRM3 | c.1938C>T p.L646= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs756859444; called by muse, mutect2, varscan2
- ITIH2 | c.1689C>T p.D563= | Silent (SNP) | VAF 40/68 reads (59%) | catalogued as rs553454623, COSV64434047, COSV64435365; called by muse, mutect2, varscan2
- IVL | c.882G>A p.K294= | Silent (SNP) | VAF 163/386 reads (42%) | called by muse, mutect2, varscan2
- NXPE3 | c.1560C>G p.L520= | Silent (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2, varscan2
- OR5T2 | c.828C>T p.V276= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV57588580; called by muse, mutect2, varscan2
- PPP1R2C | c.549G>A p.A183= | Silent (SNP) | VAF 72/181 reads (40%) | catalogued as rs1374203406; called by muse, mutect2, varscan2
- SESTD1 | c.1038G>A p.E346= | Silent (SNP) | VAF 64/203 reads (32%) | called by muse, mutect2, varscan2
- SIX2 | c.681C>T p.S227= | Silent (SNP) | VAF 139/358 reads (39%) | called by muse, mutect2, varscan2
- SLC17A9 | c.442C>A p.R148= | Silent (SNP) | VAF 113/421 reads (27%) | catalogued as rs1467659598; called by muse, mutect2, varscan2
- VPS35L | c.2421C>T p.D807= | Silent (SNP) | VAF 40/256 reads (16%) | called by muse, mutect2, varscan2
- VWF | c.5673C>T p.D1891= | Silent (SNP) | VAF 132/434 reads (30%) | catalogued as rs369450995; called by muse, mutect2, varscan2
- WASHC5 | c.1941C>T p.H647= | Silent (SNP) | VAF 142/416 reads (34%) | catalogued as rs371128991; called by muse, mutect2, varscan2
- WDR81 | c.3117C>T p.A1039= | Silent (SNP) | VAF 75/200 reads (38%) | catalogued as rs544045621; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95671337 C>T | 3'Flank (SNP) | VAF 92/194 reads (47%) | catalogued as rs556480912; called by muse, mutect2, varscan2
- DCDC2 | c.923-86_923-81del | Intron (DEL) | VAF 65/190 reads (34%) | called by mutect2, pindel, varscan2
- GUSBP10 | n.170C>T | RNA (SNP) | VAF 70/279 reads (25%) | catalogued as rs761509653; called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.1172+11G>A | Intron (SNP) | VAF 107/314 reads (34%) | called by muse, mutect2, varscan2
- ORMDL2 | c.-54A>T | 5'UTR (SNP) | VAF 71/190 reads (37%) | called by muse, mutect2, varscan2
- PHACTR1 | c.104-162C>T | Intron (SNP) | VAF 34/130 reads (26%) | called by muse, mutect2, varscan2
- PRM2 | c.272-11T>C | Intron (SNP) | VAF 147/495 reads (30%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.434C>G | RNA (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2
- SLC25A14 | c.594+328C>T | Intron (SNP) | VAF 17/172 reads (10%) | called by muse, mutect2
